Surgical pathology report (de-identified scan), TCGA case TCGA-86-7955, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7955-01A (Primary Tumor).

[page 1 of 4]
Case ID	OpenClinica ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments

[page 3 of 4]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 4.5 x 3.8 x 3.5 cm

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: CK7, CD15, TTF1 - positive

Laterality

Right-lower

[page 4 of 4]
Excision date

[REDACTED]

Source: NCI Genomic Data Commons file 5a7314de-778a-4696-a929-9711292a9b01 (TCGA-86-7955.D6A25F15-9117-43B7-BBD4-132914A24D16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).